Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4641, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4641-01A (Primary Tumor).

TCGA-CJ-4641

RENAL CELL CARCINOMA (9.5 CM MAXIMUM DIMENSION), CONVENTIONAL TYPE (40% CLEAR CELLS, 60% EOSINOPHILIC CELLS), FUHRMAN NUCLEAR GRADE 4, INVASIVE INTO RENAL VEIN AND RENAL SINUS ADIPOSE TISSUE. (SEE COMMENT)

COMMENT

The renal cell carcinoma is invasive into the proximal segment of the renal vein; however, the renal vein margin of resection is free of tumor. Tumor also invades into the renal sinus. Perinephric adipose tissue is free of tumor.

(A) LEFT KIDNEY - An 18.0 x 9.5 x 7.0 cm radical nephrectomy specimen. There is a 9.5 x 8.0 x 7.0 cm lobulated, poorly circumscribed, hemorrhagic and necrotic mass located in the lower and mid pole. Focal areas within this mass are pink-tan and have a fleshy appearance. The remainder of the tumor is red-brown to yellow. The tumor invades and fills the proximal portion of the renal vein, and is located 1.0 cm from the renal vein margin. The renal artery and ureter are grossly free of tumor. The tumor grossly appears to involve the renal sinus. The perinephric adipose tissue appears to be free of tumor.

Also present is a 1.5 x 0.9 x 0.7 cm grossly unremarkable adrenal gland.

SECTION CODE: A1, renal vein, renal artery, ureter margin; A2-A4, tumor in renal vein; A5, A6, tumor invading renal sinus; A7, A8, tumor with tan-pink fleshy areas; A9-A13, additional sections of tumor, including sections with perinephric fat; A14, grossly normal renal parenchyma; A15, adrenal gland, representative section.

CLINICAL HISTORY

nistration."

1

Source: NCI Genomic Data Commons file f87789e1-ea82-4b01-8175-f0798cd4a067 (TCGA-CJ-4641.A2F1393A-0D5E-406C-99EB-5B59B544EBC7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).